CCDI case PBCSID — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e2a360c5-eb0e-4af8-bcc8-f74fbac5b584

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Ventricle, NOS; Age at diagnosis: 8.8 years (3,229 days).

Biospecimens (3 samples)
- Sample 0DYFZ1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DYFZQ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DYG0I: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
